Somatic mutation profile of tumor specimen 0DP4QD from CCDI case PBCDCA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Synovial sarcoma, biphasic; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 11.5 years (4,190 days).
Specimen 0DP4QD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d43931e-9408-4f97-af60-c9da587fa72e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DP4P3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31eef581-4051-4112-90fa-502f7113cabf

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Silent 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LRP5 | c.4609G>A p.A1537T | Missense Mutation (SNP) | VAF 88/239 reads (37%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.77); catalogued as rs144376510, CM056637; called by muse, mutect2, varscan2
- LEFTY2 | c.909C>G p.A303= | Silent (SNP) | VAF 266/648 reads (41%) | called by muse, mutect2, varscan2
